Somatic mutation profile of tumor specimen 0DLHOX from CCDI case PBBYRV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.8 years (9,431 days).
Specimen 0DLHOX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 088cf50d-8f3b-465a-b885-a8185d415cc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLHOG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c277268a-fac4-47eb-884f-1cbc98490c80

The open-access MAF lists 56 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Intron 5, Nonsense Mutation 3, 3'UTR 2, Splice Site 2, Splice Region 1, RNA 1, 5'UTR 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHSG | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 99/256 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201849460; ClinVar: pathogenic; called by muse, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 139/324 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 561/692 reads (81%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATF7IP2 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 66/400 reads (17%) | catalogued as COSV100202515; called by mutect2, varscan2
- ATRX | c.5666del p.L1889Cfs*3 | Frame Shift Del (DEL) | VAF 262/306 reads (86%) | catalogued as CM161989; called by mutect2, varscan2
- CCT2 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 142/345 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1005425973; called by muse, mutect2, varscan2
- CDK7 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 207/618 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs751984356; called by muse, mutect2, varscan2
- EPHA5 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 85/476 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56651869; called by muse, mutect2, varscan2
- GBF1 | c.4000C>T p.H1334Y (on ENST00000369983 / NM_001377137.1; = p.H1333Y on NM_004193.3) | Missense Mutation (SNP) | VAF 153/478 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs1303784054; called by muse, mutect2, varscan2
- KIAA0319 | c.2371C>T p.R791* | Nonsense Mutation (SNP) | VAF 221/1310 reads (17%) | catalogued as rs756526138, COSV65501093; called by muse, mutect2, varscan2
- LRRC8B | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 136/755 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.528); catalogued as rs958710644; called by muse, mutect2, varscan2
- NFAT5 | c.1627C>G p.P543A | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs754792616; called by muse, mutect2, varscan2
- RPRD2 | c.2231C>G p.S744C | Missense Mutation (SNP) | VAF 12/391 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs1247503799; called by muse, mutect2
- RYR2 | c.3069C>T p.D1023= | Splice Region (SNP) | VAF 122/606 reads (20%) | catalogued as rs751382226, COSV63695251; called by muse, mutect2, varscan2
- SPATA31D1 | c.3352A>T p.M1118L | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100782670; called by muse, mutect2
- ABCA12 | c.3668T>C p.I1223T (on ENST00000272895 / NM_173076.3; = p.I905T on NM_015657.3) | Missense Mutation (SNP) | VAF 148/822 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AGAP2 | c.2622A>T p.E874D (on ENST00000547588 / NM_001122772.2; = p.E518D on NM_014770.4) | Missense Mutation (SNP) | VAF 85/450 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CSN1S1 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 226/615 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DNAJC3 | c.546+1G>A p.X182_splice | Splice Site (SNP) | VAF 54/325 reads (17%) | called by muse, mutect2, varscan2
- DPYSL2 | c.320A>G p.H107R | Missense Mutation (SNP) | VAF 91/760 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FAM205A | c.3751G>A p.A1251T | Missense Mutation (SNP) | VAF 96/537 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGA | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 39/830 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.102); called by muse, mutect2
- GRID2IP | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 138/652 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LGI2 | c.937G>T p.V313F | Missense Mutation (SNP) | VAF 28/642 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2
- LLGL2 | c.2827C>T p.H943Y | Missense Mutation (SNP) | VAF 281/719 reads (39%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MORC1 | c.336A>C p.K112N | Missense Mutation (SNP) | VAF 175/501 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- NKTR | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PABPC5 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 290/352 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.2126A>C p.Q709P | Missense Mutation (SNP) | VAF 60/1021 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- RASGEF1A | c.321+2T>A p.X107_splice | Splice Site (SNP) | VAF 78/419 reads (19%) | called by muse, mutect2, varscan2
- SARM1 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 135/571 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEMA6D | c.2326T>C p.S776P (on ENST00000316364 / NM_153618.2; = p.S714P on NM_020858.2) | Missense Mutation (SNP) | VAF 100/537 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SHISA2 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 32/135 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.1517A>G p.K506R | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- THOC1 | c.91A>T p.K31* | Nonsense Mutation (SNP) | VAF 90/641 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.62505C>A p.H20835Q (on ENST00000591111; = p.H13411Q on NM_003319.4) | Missense Mutation (SNP) | VAF 183/948 reads (19%) | PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DNAH9 | c.7533C>A p.T2511= | Silent (SNP) | VAF 116/601 reads (19%) | called by muse, mutect2, varscan2
- GORAB | c.963A>G p.E321= | Silent (SNP) | VAF 351/829 reads (42%) | catalogued as rs759377319; called by muse, mutect2, varscan2
- HYDIN | c.2334C>T p.S778= | Silent (SNP) | VAF 62/485 reads (13%) | called by muse, mutect2, varscan2
- ITGA3 | c.966G>A p.Q322= | Silent (SNP) | VAF 93/631 reads (15%) | called by muse, mutect2, varscan2
- MTO1 | c.438A>C p.P146= | Silent (SNP) | VAF 26/507 reads (5%) | called by muse, mutect2
- NADK | c.693C>T p.N231= | Silent (SNP) | VAF 176/482 reads (37%) | catalogued as rs199960450; called by muse, mutect2, varscan2
- OTOP1 | c.987G>T p.V329= | Silent (SNP) | VAF 123/429 reads (29%) | called by muse, mutect2, varscan2
- P4HA3 | c.621T>C p.A207= | Silent (SNP) | VAF 219/586 reads (37%) | called by muse, mutect2, varscan2
- RUBCNL | c.570G>T p.S190= | Silent (SNP) | VAF 162/792 reads (20%) | catalogued as COSV59787208; called by muse, mutect2, varscan2
- SPAG8 | c.1182G>A p.G394= | Silent (SNP) | VAF 65/412 reads (16%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.1638C>T p.P546= | Silent (SNP) | VAF 205/476 reads (43%) | catalogued as rs752373833; called by muse, mutect2, varscan2
- AMIGO1 | c.-65-13C>T | Intron (SNP) | VAF 5/42 reads (12%) | catalogued as rs1445678887, COSV63990566; called by muse, mutect2
- C3orf86 | n.699G>T | RNA (SNP) | VAF 96/185 reads (52%) | called by muse, mutect2, varscan2
- DBNL | c.-15A>G | 5'UTR (SNP) | VAF 51/190 reads (27%) | called by muse, mutect2, varscan2
- DDX56 | c.*76G>A | 3'UTR (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- DNAAF3 | c.912+24G>A | Intron (SNP) | VAF 12/182 reads (7%) | catalogued as rs1258753665; called by muse, mutect2
- KIFAP3 | c.320-2431G>T | Intron (SNP) | VAF 219/1113 reads (20%) | called by muse, mutect2, varscan2
- MSH3 | c.*13A>G | 3'UTR (SNP) | VAF 113/613 reads (18%) | called by muse, mutect2, varscan2
- NARS1 | c.1001+87del | Intron (DEL) | VAF 17/42 reads (40%) | called by mutect2, varscan2
- NPC1 | c.1654+44C>A | Intron (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
